Surgical pathology report (de-identified scan), TCGA case TCGA-IR-A3LA, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-IR-A3LA-01A (Primary Tumor).

[page 1 of 2]
Specimens Submitted:

- 1: SP: Uterus, cervix, bilateral tubes & ovaries (
- 2: SP: Cul-de-sac (
- 3: SP: Rt. external lymph node (
- 4: SP: Distal rt. external iliac lymph node (
- 5: SP: Rt. obturator lymph node (
- 6: SP: Rt. hypogastric lymph node (
- 7: SP: Lt. external iliac lymph node (
- 8: SP: Distal lt. external iliac lymph node (
- 9: SP: Lt. obturator lymph node (
- 10: SP: Lt. hypogastric lymph node
- 11: SP: Lt. periaortic lymph nodes
- 12: SP: Rt. para-aortic lymph nodes (
- 13: SP: Omentum

DIAGNOSIS:

- 1) UTERUS, CERVIX, BILATERAL TUBES AND OVARIES; TOTAL ABDOMINAL HYSTERECTOMY/BILATERAL SALPINGO-OOPHORECTOMY;
- INVASIVE ADENOCARCINOMA OF UTERINE CERVIX, ENDOMETRIOID, HIGH GRADE, POORLY DIFFERENTIATED WITH FOCAL AREAS SHOWING ANAPLASTIC FEATURES.
- THE MAXIMAL THICKNESS OF THE CERVICAL STROMAL INVASION IS 12 MM.
- THE THICKNESS OF THE CERVIX IN THE AREA OF MAXIMAL TUMOR INVASION IS 15 MM.
- NO EVIDENCE OF TUMOR MULTICENTRICITY IS IDENTIFIED.
- NO IN-SITU CARCINOMA IS IDENTIFIED.
- VASCULAR INVASION IS PRESENT.
- PERINEURAL INVASION IS PRESENT.
- NO VAGINAL EXTENSION IS IDENTIFIED.
- THE TUMOR DOES NOT EXTEND INTO UTERINE CORPUS.

X

PATH
REPORT

** Continued on next page **

ICD-0-3

adenocarcinoma, endocervical type 8384/3
Site: cervix, NOS C53.9 w 12/21/11

Re-reviewed w/ new SWG
endocervical tumor. OK

[page 2 of 2]
TSS Name/#.

- NO PARAMETRIAL INVOLVEMENT IS IDENTIFIED.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE ENDOMETRIUM IS UNREMARKABLE.
- THE MYOMETRIUM SHOWS LEIOMYOMAS.
- THE LEFT OVARY SHOWS AN EPITHELIAL INCLUSION CYST.
- ALL OTHER ADNEXAE ARE UNREMARKABLE.

- 2) CUL-DE-SAC; BIOPSY:
- FIBROVASCULAR TISSUE; NO TUMOR SEEN.
- 3) LYMPH NODES, EXTERNAL, RIGHT; EXCISION:
- BENIGN LYMPH NODES (0/2).
- 4) LYMPH NODE, EXTERNAL ILIAC, DISTAL, RIGHT; EXCISION:
- BENIGN LYMPH NODE (0/1).
- 5) LYMPH NODES, OBTURATOR, RIGHT; EXCISION:
- BENIGN LYMPH NODES (0/4).
- 6) LYMPH NODE, HYPOGASTRIC, RIGHT; EXCISION:
- BENIGN LYMPH NODE (0/1).
- 7) LYMPH NODE, EXTERNAL ILIAC, LEFT; EXCISION:
- BENIGN LYMPH NODE (0/1).
- 8) LYMPH NODE, EXTERNAL ILIAC, DISTAL, LEFT; EXCISION:
- BENIGN LYMPH NODE (0/1).
- 9) LYMPH NODES, OBTURATOR, LEFT; EXCISION:
- BENIGN LYMPH NODES (0/4).
- 10) LYMPH NODE, HYPOGASTRIC, LEFT; EXCISION:
- BENIGN LYMPH NODE (0/1).
- 11) LYMPH NODES, PERI-AORTIC, LEFT; EXCISION:
- BENIGN LYMPH NODES (0/2).
- 12) LYMPH NODE, PARA-AORTIC, RIGHT; EXCISION:
- BENIGN LYMPH NODE (0/1).
- 13) OMENTUM; BIOPSY:
- MATURE FAT.
- NO TUMOR SEEN.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Source: NCI Genomic Data Commons file b9728001-60b2-4522-8a24-74dbcddbd2b1 (TCGA-IR-A3LA.65E053F4-BCDB-40E2-A76B-1CA62FD61E1B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).